Gene-level copy-number profile of tumor specimen ALCH-B532-TTP1-A from ALCHEMIST case ALCH-B532, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 21.9 years (8,013 days).
Specimen ALCH-B532-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66792777-64c0-44b1-b85d-69635dfe3e1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B532-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/05f8262b-e02f-4c0f-8678-8171ad49f195

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 5,725; copy number 2: 52,240; copy number 3: 305; copy number 4: 35; copy number 5: 2; copy number 6: 1; copy number 7: 1; copy number 8: 1; copy number 9: 2; copy number 11: 1; copy number 15: 2; copy number 16: 3; copy number 21: 2; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,616,836–10,617,115, 1 gene (within-gene range 0–2): RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr1:222,468,094–222,470,882, 1 gene: CICP13.
- chr3:48,625,723–48,686,364, 7 genes: SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1, NCKIPSD.
- chr5:93,583,222–93,594,611, 1 gene (within-gene range 0–2): NR2F1.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–2): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes: AL773545.3, CDRT15P14.
- chr9:63,703,065–63,720,441, 2 genes: AL591438.2, CDRT15P7.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr10:101,060,029–101,068,131, 2 genes: AL133215.2, KAZALD1.
- chr10:117,473,215–117,549,546, 2 genes (within-gene range 0–2): EMX2OS, EMX2.
- chr12:131,366,660–131,371,059, 1 gene (within-gene range 0–1): AC140118.1.
- chr14:69,561,019–69,561,470, 1 gene: AL133445.1.
- chr14:104,085,686–104,115,582, 1 gene: ASPG.
- chr15:20,228,620–20,359,166, 3 genes: RHPN2P1, CHEK2P2, AC026495.1.
- chr15:22,401,208–22,406,944, 1 gene: SPATA31E3P.
- chr15:25,184,306–25,195,001, 7 genes (within-gene range 0–1): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14.
- chr15:41,828,095–41,894,053, 5 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–2): AC068397.2.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr17:46,243,606–46,245,044, 1 gene: MAPK8IP1P1.
- chr17:49,017,793–49,018,061, 1 gene (within-gene range 0–2): Metazoa_SRP.
- chr20:25,214,698–25,214,798, 1 gene (within-gene range 0–2): Y_RNA.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–1): AC004882.1, AC004882.2, CABP7.
- chr22:46,244,011–46,263,343, 2 genes: CDPF1, PKDREJ.
- chr22:46,481,329–46,481,760, 1 gene (within-gene range 0–1): AL031597.1.
- chr22:49,572,264–49,575,426, 1 gene (within-gene range 0–2): Z97192.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:205,989,585–206,000,858, 1 gene, copy number 5 (within-gene range 2–5): AC007679.1.
- chr7:37,032–37,477, 1 gene, copy number 7: AC215522.1.
- chr11:1,732,406–1,750,595, 1 gene, copy number 5 (within-gene range 3–5): IFITM10.
- chr11:3,321,862–3,335,407, 2 genes, copy number 21: NDUFA5P1, AC123788.2.
- chr21:43,169,008–43,172,805, 1 gene, copy number 8: CRYAA.
- chr21:43,414,483–43,479,534, 4 genes, copy number 6–30: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 11 (within-gene range 1–11): GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 9: AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 16: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 5,725. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
